Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3688, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3688-01A (Primary Tumor).

Diagnosis:

Colon resection material includes a moderately differentiated adenocarcinoma of the colorectal type, measuring a maximum of 2.5 cm, with infiltration of the pericolic fatty tissue with two regional lymph node metastases. Tumor-free colon resection margins.

Tumor stage: pT3 pN1 (2/13) pM1 (clinically liver metastases); G2, L1, V0, clinically R2

Source: NCI Genomic Data Commons file 3b10abd0-6b10-43e3-b516-f3882bbc5b59 (TCGA-AA-3688.311A81E8-9561-46C9-BD1A-D8C7E2A178D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).